Somatic mutation profile of tumor specimen TARGET-10-PARCZY-09A (aliquot TARGET-10-PARCZY-09A-01D) from TARGET case TARGET-10-PARCZY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (624 days).
Specimen TARGET-10-PARCZY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85a742e7-314d-4b68-b286-bded63124c38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCZY-10A (Blood Derived Normal), aliquot TARGET-10-PARCZY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7c0c7ff-ef26-4bc7-99e1-d1f923a37a5a

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MPDZ | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV59936938; called by muse, mutect2
- PITPNM2 | c.3414-1G>A p.X1138_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | catalogued as rs901451353; called by muse, mutect2, varscan2
- ALAS1 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- FAM110B | c.1080A>C p.Q360H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC16 | c.24067G>C p.V8023L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PAQR7 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALAS1 | c.468G>A p.V156= | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- CFLAR | c.993C>T p.L331= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1229111300; called by muse, mutect2
- MEIS2 | c.-98G>A | 5'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as rs1170626622, COSV54937543; called by muse, mutect2
